Somatic mutation profile of tumor specimen C3N-01261-02 (aliquot CPT0077480009) from CPTAC case C3N-01261, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 68.0 years (24,825 days).
Specimen C3N-01261-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25c43cff-bea5-4854-9f49-89700ffd0d79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01261-71 (Blood Derived Normal), aliquot CPT0077590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74878b49-a7ed-4b33-bc94-eecfff97cf0e

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Frame Shift Del 7, Intron 3, 3'UTR 3, Splice Site 2, Frame Shift Ins 1, Nonsense Mutation 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 119/278 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs5030826, CM941362, CM941363, CM941364, COSV56543026, COSV56543035, COSV56543220, COSV56562588; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC171 | c.2102A>T p.K701M | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1336708788; called by muse, mutect2
- CCDC63 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV57529692; called by muse, varscan2
- CRBN | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs774818392, COSV99214225; called by muse, mutect2, varscan2
- CRNKL1 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs757616700; called by muse, mutect2, varscan2
- CSMD3 | c.8458C>T p.P2820S (on ENST00000297405 / NM_001363185.1; = p.P2651S on NM_052900.3) | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99822296, COSV99828017; called by muse, mutect2, varscan2
- DAGLA | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 114/502 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs752345548; called by muse, mutect2, varscan2
- OVOL2 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372364390; called by muse, mutect2, varscan2
- PATE3 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV71323345; called by muse, mutect2, varscan2
- PLEKHO1 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1553821105; called by muse, mutect2
- TNXB | c.7532G>A p.G2511D (on ENST00000647633; = p.G2264D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473033; called by muse, mutect2, varscan2
- TSHZ2 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs367984099; called by muse, mutect2, varscan2
- WWTR1 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); catalogued as COSV62291505; called by muse, varscan2
- ZNF729 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 124/505 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as rs1453890244; called by muse, mutect2, varscan2
- ZNF91 | c.2140T>C p.Y714H | Missense Mutation (SNP) | VAF 57/337 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs779984352; called by muse, mutect2, varscan2
- ABHD16A | c.741+2del p.X247_splice | Splice Site (DEL) | VAF 42/156 reads (27%) | called by mutect2, pindel, varscan2
- AC098582.1 | c.1615A>T p.N539Y | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BACE1 | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C12orf4 | c.809dup p.L270Ffs*18 | Frame Shift Ins (INS) | VAF 37/172 reads (22%) | called by mutect2, pindel, varscan2
- CPN1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 153/542 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRBN | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP22 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- GPR3 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPAB | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- HSD11B1L | c.743del p.P248Lfs*15 | Frame Shift Del (DEL) | VAF 100/418 reads (24%) | called by mutect2, pindel, varscan2
- IFIH1 | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- JHY | c.1353_1354del p.K451Nfs*4 | Frame Shift Del (DEL) | VAF 55/225 reads (24%) | called by mutect2, pindel, varscan2
- KDM5C | c.4297_4298del p.R1433Dfs*38 | Frame Shift Del (DEL) | VAF 73/257 reads (28%) | called by pindel, varscan2
- KIF26A | c.2754_2763del p.I918Mfs*21 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | called by mutect2, pindel, varscan2
- LRRFIP1 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MLANA | c.225del p.Q76Kfs*50 | Frame Shift Del (DEL) | VAF 33/162 reads (20%) | called by mutect2, pindel, varscan2
- MYO3B | c.3481G>C p.G1161R | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTN4 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PBRM1 | c.4681-9_4687del p.X1561_splice (on ENST00000296302 / NM_001366071.2; = p.X1454_splice on NM_018313.5) | Splice Site (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel
- SEMA3B | c.449A>T p.E150V | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- SLC29A3 | c.209del p.F70Sfs*31 | Frame Shift Del (DEL) | VAF 105/481 reads (22%) | called by mutect2, pindel, varscan2
- SPTLC2 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 100/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SYNE1 | c.8591A>G p.H2864R (on ENST00000367255 / NM_182961.4; = p.H2871R on NM_033071.3) | Missense Mutation (SNP) | VAF 87/305 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SYNE2 | c.19258G>C p.D6420H | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBGCP3 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- USP17L2 | c.560del p.S187Lfs*55 | Frame Shift Del (DEL) | VAF 74/290 reads (26%) | called by mutect2, pindel, varscan2
- ZNF91 | c.2141A>T p.Y714F | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ASTL | c.1155G>A p.Q385= | Silent (SNP) | VAF 75/315 reads (24%) | called by muse, mutect2, varscan2
- BCL11A | c.1254C>A p.T418= (on ENST00000335712 / NM_001365609.1; = p.T452= on NM_018014.4) | Silent (SNP) | VAF 112/406 reads (28%) | called by mutect2, varscan2
- FGF3 | c.543C>T p.R181= | Silent (SNP) | VAF 44/212 reads (21%) | catalogued as COSV61925969; called by muse, mutect2, varscan2
- GSDMD | c.99C>T p.G33= | Silent (SNP) | VAF 72/282 reads (26%) | called by muse, mutect2, varscan2
- MDGA1 | c.1842G>A p.E614= | Silent (SNP) | VAF 42/278 reads (15%) | called by muse, mutect2, varscan2
- MMP14 | c.24C>T p.P8= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs757696438, COSV61289059; called by muse, mutect2, varscan2
- MPI | c.231G>A p.E77= | Silent (SNP) | VAF 110/448 reads (25%) | called by muse, mutect2, varscan2
- NT5M | c.492C>T p.D164= | Silent (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- OBSCN | c.3438T>C p.C1146= | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as COSV99485627; called by muse, mutect2
- SARM1 | c.1368C>T p.G456= | Silent (SNP) | VAF 74/268 reads (28%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.2229C>T p.F743= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs775585338; called by muse, mutect2, varscan2
- LITAF | c.*1396G>T | 3'UTR (SNP) | VAF 32/126 reads (25%) | catalogued as rs1261998181; called by muse, mutect2, varscan2
- MATR3 | c.*1862del | 3'UTR (DEL) | VAF 81/388 reads (21%) | called by mutect2, pindel, varscan2
- MATR3 | c.*1858A>T | 3'UTR (SNP) | VAF 83/364 reads (23%) | called by mutect2, varscan2
- OBSCN | c.18661+3164G>T | Intron (SNP) | VAF 87/389 reads (22%) | called by muse, mutect2, varscan2
- PVALEF | c.-468C>A | 5'UTR (SNP) | VAF 55/213 reads (26%) | called by muse, mutect2, varscan2
- SEC1P | n.582T>C | RNA (SNP) | VAF 98/367 reads (27%) | called by muse, mutect2, varscan2
- ZBTB48 | c.1137+161A>T | Intron (SNP) | VAF 40/232 reads (17%) | called by muse, mutect2, varscan2
- ZFYVE21 | c.139-20C>G | Intron (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
